Somatic mutation profile of tumor specimen TCGA-YU-A94I-01A (aliquot TCGA-YU-A94I-01A-11D-A435-10) from TCGA case TCGA-YU-A94I, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Yolk sac tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.7 years (24,349 days).
Specimen TCGA-YU-A94I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bd800a8-95ba-473c-b81a-0aa64661e5c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YU-A94I-10A (Blood Derived Normal), aliquot TCGA-YU-A94I-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3bcb446-197c-44d3-80bc-79cdf0ed562e

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 7, Nonsense Mutation 4, Intron 3, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, In Frame Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP63 | c.1094C>A p.S365* | Nonsense Mutation (SNP) | VAF 46/123 reads (37%) | hotspot (GDC flag); catalogued as COSV53202265, COSV53220854; called by muse, mutect2, varscan2
- ARID1A | c.1609C>T p.Q537* | Nonsense Mutation (SNP) | VAF 53/100 reads (53%) | catalogued as COSV100251003; called by muse, mutect2, varscan2
- C2orf16 | c.1273A>T p.S425C | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as COSV68645672; called by muse, mutect2, varscan2
- CACNA1H | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV62001657; called by muse, mutect2, varscan2
- CRNKL1 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs1050359212; called by muse, mutect2, varscan2
- CSMD3 | c.8614C>A p.P2872T (on ENST00000297405 / NM_001363185.1; = p.P2703T on NM_052900.3) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV52191919; called by muse, mutect2, varscan2
- DGLUCY | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV56364892; called by muse, mutect2, varscan2
- FUZ | c.755C>A p.P252Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376948728; called by muse, mutect2, varscan2
- MEI1 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 83/90 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374534859; called by muse, mutect2, varscan2
- NFXL1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61198128; called by muse, mutect2, varscan2
- PARP15 | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 73/112 reads (65%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs1469180621; called by muse, mutect2, varscan2
- PRSS57 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs372538839, COSV51261670; called by muse, mutect2, varscan2
- QRICH2 | c.2296G>A p.V766I | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as rs1168959483; called by muse, mutect2, varscan2
- SPTA1 | c.5432+1G>A p.X1811_splice | Splice Site (SNP) | VAF 9/119 reads (8%) | catalogued as COSV63749838, COSV63758259; called by muse, mutect2
- SPTBN5 | c.7013G>A p.R2338Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs563656968; called by muse, mutect2, varscan2
- SYNJ1 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs781599934; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF9B | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 133/298 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs372088655; called by muse, mutect2, varscan2
- TTC14 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV56011414; called by muse, mutect2, varscan2
- UBXN4 | c.704T>A p.M235K | Missense Mutation (SNP) | VAF 87/349 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs747973307; called by muse, mutect2, varscan2
- ZFP64 | c.1615C>T p.R539W | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs780585554; called by muse, varscan2
- ASNSD1 | c.1747C>T p.L583F | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- CDR2 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNGA1 | c.735T>G p.D245E | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CREBBP | c.542_543del p.F181* | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- DHX15 | c.302_303insA p.H102Afs*15 | Frame Shift Ins (INS) | VAF 25/126 reads (20%) | called by mutect2, varscan2
- DPP3 | c.1077G>A p.W359* | Nonsense Mutation (SNP) | VAF 77/100 reads (77%) | called by muse, mutect2, varscan2
- EEF1D | c.254C>G p.A85G | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FOXQ1 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FTSJ3 | c.1714_1715del p.Q572Dfs*9 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by pindel, varscan2
- HECTD1 | c.6494_6496del p.G2165del | In Frame Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- HTR1D | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD15 | c.136C>A p.P46T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRBA1 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LARP4B | c.1957A>T p.I653F | Missense Mutation (SNP) | VAF 59/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- POLA1 | c.1796A>G p.K599R | Missense Mutation (SNP) | VAF 227/492 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPM1D | c.1642A>T p.K548* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- SLC43A1 | c.43A>T p.M15L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SYCP3 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TAB2 | c.788A>G p.N263S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPH1 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, varscan2
- TPH1 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.371); called by muse, varscan2
- TRIM16 | c.1502T>A p.F501Y | Missense Mutation (SNP) | VAF 49/159 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- ZFHX4 | c.8646_8651dup p.H2882_D2883dup | In Frame Ins (INS) | VAF 17/60 reads (28%) | called by mutect2, varscan2
- ZNF16 | c.1790G>A p.G597E | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR2A | c.423C>G p.L141= | Silent (SNP) | VAF 63/218 reads (29%) | called by muse, mutect2, varscan2
- AK7 | c.15G>A p.E5= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV99967633; called by muse, mutect2
- EIF4B | c.96C>G p.T32= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs373400973; called by muse, mutect2, varscan2
- FANCD2 | c.3756C>T p.G1252= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV55033377; called by muse, mutect2, varscan2
- GATAD2B | c.1521G>A p.T507= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as rs753763024, COSV64086249; called by muse, mutect2, varscan2
- HSD17B4 | c.192T>C p.N64= (on ENST00000414835 / NM_001199291.3; = p.N39= on NM_000414.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/75 reads (41%) | called by muse, varscan2
- PA2G4 | c.1074C>T p.L358= | Silent (SNP) | VAF 60/199 reads (30%) | called by muse, mutect2, varscan2
- ABHD11 | c.634-47C>T | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2997G>A | RNA (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- RNF130 | c.443-2012A>G | Intron (SNP) | VAF 57/134 reads (43%) | called by muse, mutect2, varscan2
- TBCE | c.371+4810A>T | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
